Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4703, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4703-01A (Primary Tumor).

FINAL DIAGNOSIS**LEFT KIDNEY, NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE WITH SARCOMATOID FEATURES WITH LARGE "RHABDOID"-TYPE CELLS WITH BIZARRE ATYPIA (See Comment).
- B. FUHRMAN NUCLEAR GRADE IS 4/4.
- C. RENAL CELL CARCINOMA GROWS IN ACINAR, PAPILLARY AND TUBULAR PATTERNS OF GROWTH.
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.5 CM.
- E. THE NEOPLASM EXTENDS THROUGH THE RENAL CAPSULE WITH MULTIPLE SATELLITE NODULES, BUT IS CONFINED WITHIN GEROTA FASCIA.
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- G. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- J. THE ADRENAL GLAND IS NOT SUBMITTED.
- K. NO LYMPH NODES ARE IDENTIFIED.
- L. TNM STAGE: pT3 NX MX.
- M. TNM HISTOLOGIC GRADE = G4.

COMMENT:

This tumor has an unusual morphology with areas closely resembling clear cell type carcinoma which are admixed with additional more high grade spindle cell components including those with tumor nuclei that are markedly enlarged, with macronuclei, irregular nuclear shapes and pleomorphism. In addition, there are areas with glandular formation, reminiscent of an "intestinal" type morphology. Taken together, these are unusual histological findings.

Source: NCI Genomic Data Commons file 8940581d-a89b-4289-9f66-8d77651b0aa1 (TCGA-B0-4703.15843D37-AD2B-4997-AE96-FAB2C69C03C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).